Somatic mutation profile of tumor specimen TCGA-EA-A3HR-01A (aliquot TCGA-EA-A3HR-01A-11D-A20U-09) from TCGA case TCGA-EA-A3HR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 57.4 years (20,980 days).
Specimen TCGA-EA-A3HR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a46b5aa-d09b-44c9-a6da-fc15eab46663.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A3HR-10A (Blood Derived Normal), aliquot TCGA-EA-A3HR-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a5c754e-f0ad-4b79-bca8-a4b2a82f1726

The open-access MAF lists 75 somatic variants for this specimen: 52 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 22, Nonsense Mutation 8, RNA 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL1 | c.1915C>T p.R639* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as COSV59336112; called by muse, mutect2, varscan2
- ACAN | c.5729G>A p.R1910K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV61364415; called by muse, mutect2, varscan2
- ACSL5 | c.809G>A p.G270E (on ENST00000354273; = p.G326E on NM_016234.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767611100, COSV61132078; called by muse, mutect2, varscan2
- ADGRD1 | c.1100G>C p.G367A | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55447849, COSV55450649; called by muse, mutect2, varscan2
- ATRNL1 | c.1770C>T p.N590= | Splice Region (SNP) | VAF 12/30 reads (40%) | catalogued as rs561349730, COSV61797166; called by muse, mutect2, varscan2
- BICDL2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1187956590, COSV54157068; called by muse, mutect2, varscan2
- CABIN1 | c.5275G>T p.E1759* | Nonsense Mutation (SNP) | VAF 77/150 reads (51%) | catalogued as COSV54085262; called by muse, mutect2, varscan2
- COL11A1 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs192313594; called by muse, mutect2, varscan2
- COL12A1 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs749797723, COSV59400805; called by muse, mutect2, varscan2
- DHX36 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as COSV57674794; called by muse, mutect2, varscan2
- DNAH8 | c.11682C>G p.I3894M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59463135; called by muse, mutect2, varscan2
- EIF3G | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs771861822, COSV53459195; called by muse, mutect2, varscan2
- EPRS1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV65100200; called by muse, mutect2, varscan2
- FAM13C | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53252019, COSV99513230; called by muse, varscan2
- FAT1 | c.9998_9999del p.P3333Rfs*13 | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | catalogued as COSV71672601; called by mutect2, pindel, varscan2
- ITPR1 | c.5046G>T p.M1682I (on ENST00000354582; = p.M1667I on NM_002222.7) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56991772; called by muse, mutect2, varscan2
- KRT84 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as rs368100864; called by muse, mutect2, varscan2
- KRTAP1-3 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as COSV60336592; called by muse, varscan2
- KRTAP1-3 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 74/248 reads (30%) | catalogued as COSV60335481, COSV60336603; called by muse, varscan2
- LNX2 | c.1950G>C p.M650I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV60336987; called by muse, mutect2, varscan2
- LPXN | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1289935953, COSV67717619; called by muse, mutect2, varscan2
- MPO | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767409795, COSV51859073; called by muse, mutect2, varscan2
- MROH8 | c.1453C>G p.L485V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.668); catalogued as COSV54121180; called by muse, mutect2, varscan2
- MUC5B | c.14093C>G p.S4698* | Nonsense Mutation (SNP) | VAF 62/234 reads (26%) | catalogued as COSV71594021; called by muse, mutect2
- MYH7 | c.2102G>A p.G701D | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100806473; called by muse, mutect2
- NASP | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV63113833; called by muse, mutect2, varscan2
- NXPE3 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as rs779031147, COSV56290962; called by muse, mutect2, varscan2
- OGDH | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as rs755554782, COSV56053427; called by muse, mutect2, varscan2
- OR12D3 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV65827299; called by muse, mutect2, varscan2
- OR5L2 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65724572, COSV65725079; called by muse, mutect2, varscan2
- PCSK6 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as rs766469441, COSV61855900; called by muse, mutect2, varscan2
- PHKA1 | c.2716C>T p.R906* | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as rs782241425, COSV59808243; called by muse, mutect2, varscan2
- PIWIL3 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs141396207; called by muse, mutect2, varscan2
- POLN | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV67026295; called by muse, mutect2
- PREPL | c.2047G>C p.D683H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764767440, COSV53217931; called by muse, mutect2, varscan2
- PTX4 | c.650C>G p.S217C (on ENST00000447419 / NM_001328608.2; = p.S212C on NM_001013658.1) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53517979; called by muse, mutect2, varscan2
- ROR2 | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.304); catalogued as rs151187583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIRPB1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV53539128, COSV53539741; called by muse, mutect2, varscan2
- SNRPN | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV57595625; called by muse, mutect2, varscan2
- SPDYE3 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100193897, COSV60107732; called by muse, mutect2, varscan2
- TAPBP | c.578C>G p.S193* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV70457425; called by muse, mutect2, varscan2
- THOC5 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV63799653; called by muse, mutect2, varscan2
- TRBC2 | c.292G>C p.V98L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs782356332; called by muse, mutect2, varscan2
- TULP4 | c.756G>C p.Q252H | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV65573688; called by muse, varscan2
- USH2A | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs373190681, CM149915, COSV56437947; called by muse, mutect2
- WDR19 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV56467477; called by muse, mutect2, varscan2
- WDR45B | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV66408746; called by muse, mutect2, varscan2
- WDR90 | c.5110G>A p.D1704N | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as COSV53472411; called by muse, mutect2, varscan2
- XIRP1 | c.4088G>A p.R1363Q | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs781051406, COSV61139691; called by muse, mutect2, varscan2
- ZBTB45 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1343410431, COSV100657772; called by muse, mutect2, varscan2
- ZNF222 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 213/260 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1290649407, COSV51827484; called by muse, mutect2, varscan2
- ZNF829 | c.926C>G p.S309* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV66986663; called by muse, mutect2, varscan2
- CDH11 | c.843C>T p.A281= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs746814113, COSV51768799, COSV99217306; called by muse, mutect2, varscan2
- COL27A1 | c.1053G>A p.A351= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as rs1421440467, COSV100620667, COSV100621236; called by muse, mutect2, varscan2
- ECT2 | c.1026A>G p.Q342= (on ENST00000392692 / NM_001349098.2; = p.Q311= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs547764309, COSV99221737; called by muse, mutect2
- FBXL13 | c.618G>A p.V206= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV57540890; called by muse, mutect2, varscan2
- FBXL20 | c.15G>A p.V5= | Silent (SNP) | VAF 69/295 reads (23%) | catalogued as COSV52901143; called by muse, mutect2, varscan2
- GBF1 | c.1932C>T p.G644= (on ENST00000369983 / NM_001377137.1; = p.G643= on NM_004193.3) | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV64146866; called by muse, mutect2, varscan2
- HTR1A | c.426C>T p.I142= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as COSV60501817; called by muse, mutect2, varscan2
- HTR1D | c.642C>T p.I214= | Silent (SNP) | VAF 25/36 reads (69%) | catalogued as COSV58448451; called by muse, mutect2, varscan2
- MAN2C1 | c.519G>C p.L173= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV51228546, COSV99145722; called by muse, mutect2, varscan2
- NPC1 | c.3306C>T p.L1102= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as rs756938143, COSV52575448; called by muse, mutect2, varscan2
- NTRK1 | c.2124C>T p.S708= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as rs1371693296, COSV62326969; called by muse, mutect2, varscan2
- PCDH11X | c.4038C>T p.P1346= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs747351611, COSV53484754; called by muse, mutect2, varscan2
- PCDHB13 | c.831G>A p.E277= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV53394358, COSV53398727; called by muse, mutect2, varscan2
- PHKG1 | c.183G>A p.P61= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as rs56278042, COSV52082082; called by muse, mutect2, varscan2
- RBM10 | c.1482G>A p.Q494= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV61310349; called by muse, mutect2, varscan2
- RGL1 | c.2103C>G p.V701= (on ENST00000360851 / NM_001297672.2; = p.V736= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100487580, COSV58989568; called by muse, mutect2, varscan2
- SUPT3H | c.291G>A p.L97= (on ENST00000371460 / NM_181356.3; = p.L86= on NM_003599.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV60944305; called by muse, mutect2, varscan2
- SYNE1 | c.3897G>A p.A1299= (on ENST00000367255 / NM_182961.4; = p.A1306= on NM_033071.3) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV55034127; called by muse, mutect2, varscan2
- TAPBP | c.1086C>T p.L362= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV70457420; called by muse, mutect2, varscan2
- TNFRSF8 | c.1662G>A p.A554= | Silent (SNP) | VAF 45/87 reads (52%) | catalogued as rs376213546, COSV55800526; called by muse, mutect2, varscan2
- XKR4 | c.753C>T p.C251= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs1165989446, COSV100533769, COSV59326918; called by muse, mutect2, varscan2
- ZNF555 | c.339C>A p.L113= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV62073519; called by muse, mutect2, varscan2
- DCHS2 | n.5337G>A | RNA (SNP) | VAF 19/47 reads (40%) | catalogued as rs1212090303, COSV61775433; called by muse, mutect2, varscan2
